Surgical pathology report (de-identified scan), TCGA case TCGA-55-7910, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-55-7910-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology Final Report Temporary Copy

Case: [REDACTED]

Collected: [REDACTED]

Ordered by: [REDACTED]

P [REDACTED]

IC [REDACTED]

Location: [REDACTED]

Final Diagnosis

Left lower lobe of lung, surgical resection with operating room consultation:

Pulmonary adenocarcinoma (7 cm in maximum dimension).

Tumor does not penetrate lung pleural surface.

Bronchial margins of surgical excision free.

No lymphovascular invasion is identified.

Four (4) peribronchial lymph nodes negative.

#5 subaortic lymph node dissection:

Multiple fragments of lymphoid tissue negative for malignancy.

#9 Pulmonary ligament lymph node dissection:

Two (2) negative lymph nodes.

#6 Para-aortic lymph node dissection:

One (1) negative node.

#8 Paraesophageal lymph node dissection:

Three (3) negative nodes.

#7 Subcarinal lymph node dissection:

One (1) negative node.

Comment: This case corresponds to a pathological AJCC stage of T2b,N0.

Clinical Information

Adenocarcinoma LLL.

Operating Room Consultation

Left lower lobe lung adenocarcinoma.

ORC – Tissue from tumor, paranormal and normal submitted for genomics studies.

No FS requested.

Visceral pleura inked black over tumor. [REDACTED]

Gross Description

[page 2 of 2]
Surgical Pathology Final Report

Temporary Copy

Page 2 of 2

Case: [REDACTED]

Collected: [REDACTED]

Ordered by: [REDACTED]

"A, Left lower lung lobe." The specimen consists of a 19.5 x 13.6 x 6.8 cm portion of lung. The pleural surface is blue-gray. There is a 2 cm firm, puckered area present on the pleural surface. This area will be inked black. On sectioning, there is a 7 x 6.7 x 5.7 cm soft, gray-tan, friable mass, which abuts the pleural surface and comes to within 5 cm of the bronchial margin. The remaining lung parenchyma is red-brown and markedly congested, and no additional lesions or areas of interest are grossly identified. Four possible peribronchial lymph nodes are identified. These range in size from 1.2 to 1.4 cm. "A1," bronchial margin; "A2," vascular margins; "A3," mass with overlying pleura; "A4-A5," mass; "A6," mass with adjacent parenchyma; "A7-A8," peribronchial lymph nodes.

Received for research purposes is one yellow cassette labeled [REDACTED] one green cassette labeled [REDACTED] and one blue cassette labeled [REDACTED]

"B, 5 subaortic." The specimen consists of a 1.4 x 1.3 cm ragged, anthracotic portion of lymphoid tissue. "B," fragments, all.

"C, #9 pulmonary ligament." The specimen consists of 2 anthracotic lymph nodes, which measure 0.7 and 0.8 cm. "C," 4p, all.

"D, #6 paraaortic." The specimen consists of a 1.3 x 1 cm red-gray lymph node. "D," 3p, all.

"E, #8 paraesophageal." The specimen consists of 3 portions of red-gray lymphoid tissue ranging in size from 0.7 x 0.5 to 2.2 x 1.2 cm. "E1-E3," fragments, all.

"F, #7 subcarinal." The specimen consists of a 1.8 x 1 cm red-gray lymph node with a small amount of attached fat. "F," 2p, all.

([REDACTED])

[REDACTED]

Source: NCI Genomic Data Commons file 490c56ac-9cd9-4552-af9c-63a6abe77020 (TCGA-55-7910.C205ABDA-DFE0-43B1-A265-4C41125216FE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).